Somatic mutation profile of tumor specimen 0DUKHC from CCDI case PBCLLF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 23.6 years (8,628 days).
Specimen 0DUKHC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b515a28-c8f9-4036-b486-f480ab950f75.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUKIX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e6b9950-d720-4466-9cce-bb79d2261f6a

The open-access MAF lists 47 somatic variants for this specimen: 32 protein-altering or splice-affecting, 7 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 7, Intron 3, Frame Shift Del 3, Nonsense Mutation 3, Splice Region 2, 3'UTR 2, In Frame Del 2, 5'Flank 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.3880_3882del p.K1294del | In Frame Del (DEL) | VAF 420/1134 reads (37%) | catalogued as rs72664235; ClinVar: pathogenic; called by mutect2, varscan2
- H3-3A | c.103G>A p.G35R | Missense Mutation (SNP) | VAF 267/784 reads (34%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1553260624, COSV64731793, COSV64731830, COSV64732212; ClinVar: other; called by muse, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 408/1109 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG4 | c.1916G>A p.R639H | Missense Mutation (SNP) | VAF 233/686 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs746685392, COSV56642005, COSV56643302; called by muse, mutect2, varscan2
- CACNA1A | c.4630G>A p.A1544T | Missense Mutation (SNP) | VAF 60/1104 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as rs761579946, COSV100803636; ClinVar: uncertain significance; called by muse, mutect2
- DOCK3 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 332/865 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs746629423; called by muse, mutect2, varscan2
- LMOD1 | c.85A>T p.M29L | Missense Mutation (SNP) | VAF 321/887 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV66172043; called by mutect2, varscan2
- MCAT | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 327/889 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs764245496, COSV51792581, COSV51793681; called by muse, mutect2, varscan2
- MYO9A | c.3878G>A p.R1293H | Missense Mutation (SNP) | VAF 187/422 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs183156147; called by muse, mutect2, varscan2
- NF1 | c.6691G>T p.E2231* (on ENST00000358273 / NM_001042492.3; = p.E2210* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 291/411 reads (71%) | catalogued as CM000814, COSV62192689, COSV62219494; called by muse, mutect2, varscan2
- NPHP4 | c.3877G>A p.V1293M | Missense Mutation (SNP) | VAF 404/1047 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs769488870; called by muse, mutect2, varscan2
- POLR1B | c.1141T>C p.F381L | Missense Mutation (SNP) | VAF 296/789 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1007226107; called by muse, mutect2, varscan2
- SEC14L5 | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 312/823 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs190855004; called by muse, mutect2, varscan2
- SOWAHA | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 108/260 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1340105895; called by muse, mutect2, varscan2
- TP53 | c.965del p.P322Hfs*23 | Frame Shift Del (DEL) | VAF 310/416 reads (75%) | catalogued as COSV52729459, COSV52826955; called by mutect2, varscan2
- ZNF596 | c.140-8C>G | Splice Region (SNP) | VAF 477/897 reads (53%) | catalogued as rs757963538; called by muse, mutect2, varscan2
- ATRX | c.5156A>T p.D1719V | Missense Mutation (SNP) | VAF 329/389 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCT7 | c.160+5_160+9del | Splice Region (DEL) | VAF 293/940 reads (31%) | called by mutect2, varscan2
- CDC45 | c.621G>A p.W207* | Nonsense Mutation (SNP) | VAF 361/1010 reads (36%) | called by muse, mutect2, varscan2
- FBXW7 | c.544_548del p.S182Gfs*72 (on ENST00000281708 / NM_001349798.2; = p.S102Gfs*72 on NM_018315.5) | Frame Shift Del (DEL) | VAF 308/474 reads (65%) | called by mutect2, varscan2
- FRY | c.1988T>C p.L663P | Missense Mutation (SNP) | VAF 521/1317 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- INPP5K | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 305/435 reads (70%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LY75 | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 429/1263 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NF1 | c.6595T>G p.L2199V (on ENST00000358273 / NM_001042492.3; = p.L2178V on NM_000267.3) | Missense Mutation (SNP) | VAF 396/573 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- OTUD4 | c.1109C>G p.P370R (on ENST00000447906 / NM_001366057.1; = p.P305R on NM_001102653.1) | Missense Mutation (SNP) | VAF 528/756 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- PURG | c.441_443del p.R149del | In Frame Del (DEL) | VAF 181/466 reads (39%) | called by mutect2, varscan2
- RASSF8 | c.703G>T p.E235* | Nonsense Mutation (SNP) | VAF 479/1288 reads (37%) | called by mutect2, varscan2
- TRPA1 | c.1707C>G p.S569R | Missense Mutation (SNP) | VAF 735/1850 reads (40%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- WDR97 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 270/632 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- XPO1 | c.629A>G p.Q210R | Missense Mutation (SNP) | VAF 502/1357 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- ZNF273 | c.1031_1032del p.K344Tfs*6 | Frame Shift Del (DEL) | VAF 74/181 reads (41%) | called by mutect2, varscan2
- ZNF578 | c.1744T>G p.S582A | Missense Mutation (SNP) | VAF 22/561 reads (4%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.006); called by muse, mutect2
- CFAP157 | c.1212G>T p.L404= | Silent (SNP) | VAF 223/906 reads (25%) | called by muse, mutect2, varscan2
- DLK1 | c.48T>A p.A16= | Silent (SNP) | VAF 174/441 reads (39%) | called by muse, mutect2, varscan2
- MARF1 | c.2865C>T p.D955= | Silent (SNP) | VAF 342/900 reads (38%) | catalogued as rs1193933686; called by muse, mutect2, varscan2
- MOCS3 | c.1332G>A p.G444= | Silent (SNP) | VAF 366/1062 reads (34%) | called by mutect2, varscan2
- RP1 | c.5301A>T p.A1767= | Silent (SNP) | VAF 426/1141 reads (37%) | called by muse, mutect2, varscan2
- UMOD | c.600C>T p.R200= | Silent (SNP) | VAF 436/1129 reads (39%) | catalogued as rs1222249699; called by muse, mutect2, varscan2
- ZNF473 | c.105G>A p.A35= | Silent (SNP) | VAF 251/649 reads (39%) | catalogued as rs374998578; called by muse, mutect2, varscan2
- CFAP65 | c.-2-93C>G | Intron (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- FBN1 | c.-58C>T | 5'UTR (SNP) | VAF 51/118 reads (43%) | called by muse, mutect2, varscan2
- GPRC5B | chr16:19885274 G>A | 5'Flank (SNP) | VAF 194/455 reads (43%) | catalogued as rs969845519; called by muse, mutect2, varscan2
- MARK2 | c.531+18_531+20del | Intron (DEL) | VAF 177/545 reads (32%) | catalogued as rs756746620; called by mutect2, varscan2
- MUC19 | chr12:40561596 C>T | 5'Flank (SNP) | VAF 305/926 reads (33%) | catalogued as rs968780147; called by muse, mutect2, varscan2
- SCNN1B | c.*20G>A | 3'UTR (SNP) | VAF 142/375 reads (38%) | catalogued as rs755277136; ClinVar: likely benign; called by muse, mutect2, varscan2
- UNKL | c.1586-64C>T | Intron (SNP) | VAF 50/139 reads (36%) | called by muse, mutect2, varscan2
- ZBTB20 | c.*14C>A | 3'UTR (SNP) | VAF 250/601 reads (42%) | called by mutect2, varscan2
